TCGA case TCGA-D3-A51H — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50e4cdbc-b10b-4c6c-9981-68defa1a8fe0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (4)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 62.6 years (22,881 days); Days to diagnosis: 762 days (2.1 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 60.6 years (22,119 days); Year of diagnosis: 2009; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Dacarbazine + Vinblastine; Days to treatment start: 894 days (2.4 years); Days to treatment end: 1,045 days (2.9 years); Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk; Ulceration indicator: Yes.
   Pathology details: Breslow thickness category: <=1 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 62.9 years (22,957 days); Days to diagnosis: 838 days (2.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (3 entries)
- Day 838 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 838 days (2.3 years).
- Days to follow up: 1,221 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,714 days (4.7 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 0.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 78 kg; Height: 183 cm; BMI: 23.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D3-A51H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-D3-A51H-06A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-D3-A51H-06Z: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D3-A51H-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: .91; Primary melanoma mitotic rate: 0; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Subsequent known primaries: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,714 days; disease-specific survival: no event (censored), 1,714 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 838 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D3-A51H-06A-12D-A25P-01): tumor purity 0.1, ploidy 2.01, whole-genome doublings 0.
